Surgical pathology report (de-identified scan), TCGA case TCGA-19-2621, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2621-01B (Primary Tumor).

2621
SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A-C. RIGHT TEMPORAL LOBE OF BRAIN, TUMOR, BIOPSIES AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Microscopic: Necrotic tissue, suggestive of derivation from glioblastoma.
B: Microscopic: Glioblastoma.

Clinical History:

Right cerebral mass

Specimens Submitted As:

A: RT TEMPORAL LOBE TUMOR
B: RIGHT TEMPORAL BRAIN TUMOR
C: RIGHT TEMPORAL LOBE TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, and "right temporal lobe tumor", is a 0.5 x 0.5 x 0.3 cm, white-tan aggregate of soft tissue fragments. Representative sections are submitted for touch imprint and frozen section

B: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, and "right temporal brain tumor", is a 1 x 0.8 x 0.5 cm aggregate of tan-brown soft tissue fragments. The specimen is submitted for touch imprint.

C: Received in formalin, labeled with the patient's name and number, are multiple light tan to brown to pink irregular soft tissue fragments measuring 5.3 x 3.7 x 1.6 cm in aggregate. The two largest fragments are serially sectioned. On section, the tissue is pink to pale yellow-white-tan and hemorrhagic. Submitted entirely in 5 cassettes.

Summary of cassettes

A1FS

A2 remainder of tissue

B1 specimen submitted entirely in one cassette

C1-C3 largest fragment

C4 2nd largest fragment

C5 remaining tissue

Source: NCI Genomic Data Commons file 47e68855-37da-472c-9e50-fb195cba9068 (TCGA-19-2621.9A4ECD6D-B513-4902-A182-31C8792B8D1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).